Somatic mutation profile of tumor specimen TCGA-F4-6809-01A (aliquot TCGA-F4-6809-01A-11D-1835-10) from TCGA case TCGA-F4-6809, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 52.1 years (19,039 days).
Specimen TCGA-F4-6809-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97db3ed5-1991-452f-9157-1f2b2667c802.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6809-10A (Blood Derived Normal), aliquot TCGA-F4-6809-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be0a9525-3580-454a-9918-fd514320724f

The open-access MAF lists 163 somatic variants for this specimen: 123 protein-altering or splice-affecting, 34 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 34, Nonsense Mutation 11, Frame Shift Ins 4, Intron 4, Splice Site 3, RNA 2, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 42/190 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.4811T>A p.L1604H | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101329993; called by muse, mutect2
- ABCA13 | c.10188A>T p.E3396D | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as COSV71282600; called by muse, mutect2, varscan2
- AHNAK2 | c.12254C>T p.A4085V | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.963); catalogued as rs372676751; called by muse, varscan2
- APBB2 | c.272G>C p.G91A | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as rs774437105, COSV55946288; called by muse, mutect2, varscan2
- APC | c.2819C>A p.S940* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as CM095524, COSV57320637; called by muse, mutect2, varscan2
- ARFGEF1 | c.2365C>A p.R789S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141630; called by muse, mutect2, varscan2
- ATP7A | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV58441707; called by muse, varscan2
- C1QL2 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV55605834, COSV55606671; called by muse, mutect2, varscan2
- C2orf78 | c.1487C>G p.S496C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV68516248; called by muse, mutect2, varscan2
- CCDC73 | c.1050+1G>T p.X350_splice | Splice Site (SNP) | VAF 50/194 reads (26%) | catalogued as COSV100067013; called by muse, mutect2, varscan2
- CEP43 | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.451); catalogued as rs1246646693, COSV62760317; called by muse, mutect2
- CGREF1 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs373222294; called by muse, mutect2
- CHST13 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.17); catalogued as COSV60041151; called by muse, mutect2, varscan2
- CHST13 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100081065; called by muse, mutect2, varscan2
- CILP2 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs1405578771, COSV52272611; called by muse, mutect2
- CLEC4F | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as rs781850083, COSV99713660; called by muse, varscan2
- COL15A1 | c.3602T>G p.L1201R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.459); catalogued as COSV100897556; called by muse, mutect2, varscan2
- COL7A1 | c.5614G>A p.G1872S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV60390517; called by muse, mutect2, varscan2
- CYP4X1 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as rs1335936100, COSV64149501, COSV64149596; called by muse, mutect2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, varscan2
- DLGAP2 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV70093241; called by muse, mutect2, varscan2
- DNAH7 | c.3303A>T p.E1101D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56749792; called by muse, mutect2, varscan2
- DNAJC18 | c.722T>C p.I241T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100122096; called by muse, mutect2
- DNMT3B | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52414567, COSV52420202; called by muse, mutect2, varscan2
- DOCK2 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56938995; called by muse, mutect2, varscan2
- DSCAM | c.2539A>T p.I847F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV68019905; called by muse, mutect2, varscan2
- DYNC1I1 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.048); catalogued as COSV61454881; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1542G>C p.K514N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV62566476; called by muse, mutect2, varscan2
- EIF3M | c.244T>A p.L82M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV60072230; called by muse, varscan2
- EIF3M | c.245T>A p.L82* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV60072238; called by muse, varscan2
- EIF4G3 | c.1846A>G p.T616A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs752210615, COSV51672920; called by muse, mutect2, varscan2
- ENAM | c.2276T>C p.L759P | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV101253005; called by muse, mutect2, varscan2
- ENPEP | c.1694G>C p.R565T | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54446427; called by muse, mutect2, varscan2
- ENPP2 | c.240T>G p.C80W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307941; called by muse, mutect2, varscan2
- EXPH5 | c.4138G>T p.E1380* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99761266; called by muse, mutect2, varscan2
- FAM47A | c.1804A>G p.R602G | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV60493596; called by muse, mutect2, varscan2
- FBN3 | c.6241T>C p.S2081P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs1276517334, COSV54452331; called by muse, mutect2, varscan2
- FBXL19 | c.1742G>A p.G581D | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV57940397; called by muse, mutect2, varscan2
- FBXO30 | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV52790082; called by muse, mutect2, varscan2
- FLG | c.726A>C p.E242D | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.622); catalogued as COSV100911355; called by muse, mutect2
- FTSJ1 | c.566G>C p.S189T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99191389; called by muse, mutect2, varscan2
- GCNT2 | c.1203_1204insA p.F402Ifs*6 (on ENST00000379597 / NM_001374747.1; = p.F400Ifs*6 on NM_001491.3) | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | catalogued as COSV53940811; called by mutect2, pindel, varscan2
- GDPD5 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61126071; called by muse, mutect2
- GIMAP1 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs1463145921, COSV100212049; called by muse, varscan2
- GOLGB1 | c.5668G>T p.E1890* | Nonsense Mutation (SNP) | VAF 43/239 reads (18%) | catalogued as COSV100510568; called by muse, mutect2, varscan2
- GPR42 | c.364T>A p.W122R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.103); catalogued as COSV101497377; called by muse, mutect2, varscan2
- GUSB | c.1574T>G p.F525C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59220718; called by muse, mutect2, varscan2
- HAL | c.1868A>G p.Y623C | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99701322; called by muse, mutect2
- IDO2 | c.844G>T p.G282C (on ENST00000389060; = p.G295C on NM_194294.2) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV58423249, COSV58425555; called by muse, mutect2, varscan2
- IFT122 | c.237C>G p.I79M | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56199474; called by muse, mutect2, varscan2
- IL9R | c.43A>C p.S15R | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV54898010; called by muse, mutect2, varscan2
- INPP5E | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99257105; called by muse, mutect2
- KRTAP15-1 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV61876938; called by muse, mutect2, varscan2
- LRRC36 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99338565; called by mutect2, varscan2
- LRRTM4 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as rs1396734599, COSV69138746, COSV69141749; called by muse, mutect2, varscan2
- LTBP4 | c.1901A>G p.H634R (on ENST00000308370 / NM_001042544.1; = p.H597R on NM_003573.2) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52575177; called by muse, mutect2
- MAGEB2 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.137); catalogued as COSV66780120; called by muse, mutect2
- MAP10 | c.1449G>C p.K483N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs770365421, COSV101406484; called by muse, mutect2, varscan2
- MAP1B | c.6490C>A p.P2164T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57093166; called by muse, mutect2, varscan2
- MAP4K2 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV53639928; called by muse, mutect2
- MAPRE1 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV100980386; called by muse, mutect2
- MGAT3 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.192); catalogued as COSV100361803; called by muse, mutect2, varscan2
- MLF1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); catalogued as rs201952489, COSV63032290; called by muse, mutect2, varscan2
- MNS1 | c.1054C>G p.Q352E | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV53067522; called by muse, mutect2, varscan2
- MON2 | c.3925G>T p.V1309F | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54802337; called by muse, mutect2, varscan2
- MOV10L1 | c.555+2T>G p.X185_splice | Splice Site (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99433400; called by muse, mutect2, varscan2
- MTA2 | c.1017-1G>A p.X339_splice | Splice Site (SNP) | VAF 18/76 reads (24%) | catalogued as COSV53468479; called by muse, mutect2, varscan2
- MTCP1 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.995); catalogued as rs1557291991, COSV62898346; called by muse, mutect2
- NKRF | c.700A>C p.K234Q | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV58660463; called by muse, mutect2, varscan2
- NPY4R | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs149694580; called by muse, mutect2
- OR4A15 | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.25); catalogued as COSV59035192; called by muse, mutect2, varscan2
- OR4A16 | c.817T>C p.Y273H | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs752118228, COSV59041687; called by muse, mutect2, varscan2
- OR4K15 | c.1004T>A p.V335D (on ENST00000305051; = p.V311D on NM_001005486.1) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); catalogued as COSV100521010; called by muse, mutect2
- OR4K15 | c.1006T>A p.S336T (on ENST00000305051; = p.S312T on NM_001005486.1) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); catalogued as COSV100521011; called by muse, mutect2
- P3H1 | c.780C>A p.Y260* | Nonsense Mutation (SNP) | VAF 19/115 reads (17%) | catalogued as COSV52531291; called by muse, mutect2, varscan2
- PARP14 | c.2834T>C p.F945S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV71734048; called by muse, mutect2, varscan2
- PCDHA2 | c.1844C>T p.T615I | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); catalogued as COSV65364151; called by muse, mutect2, varscan2
- PCDHGA7 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.135); catalogued as rs762319044, COSV99534637; called by muse, mutect2, varscan2
- PDE8B | c.1907T>C p.V636A | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV99366512; called by muse, mutect2, varscan2
- PDZD2 | c.2892C>A p.C964* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99224443; called by muse, mutect2, varscan2
- PLEKHH2 | c.2921C>T p.T974I | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1304729526; called by muse, mutect2
- PPL | c.13T>A p.F5I | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100630640; called by muse, mutect2
- PTCD2 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1387200420, COSV57336674; called by muse, mutect2, varscan2
- QKI | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs779943694, COSV99274669, COSV99274714; called by muse, mutect2, varscan2
- REL | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 105/344 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104400087, COSV54361992; called by muse, mutect2, varscan2
- RGS8 | c.121G>A p.A41T (on ENST00000367556 / NM_001369564.2; = p.A59T on NM_033345.3) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.299); catalogued as rs768666544, COSV51114905; called by mutect2, varscan2
- ROBO2 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs751711354, COSV59893559, COSV59899603; called by muse, varscan2
- SEMA5B | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs916876645, COSV52093569; called by muse, mutect2, varscan2
- SETD2 | c.4912C>A p.Q1638K | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100338581; called by muse, mutect2, varscan2
- SH3TC1 | c.3138C>G p.Y1046* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99794634; called by muse, mutect2, varscan2
- SHOC1 | c.4274G>A p.R1425H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs533026166, COSV59497070; called by muse, mutect2, varscan2
- SLAMF7 | c.743G>A p.W248* | Nonsense Mutation (SNP) | VAF 42/155 reads (27%) | catalogued as rs370138407; called by muse, mutect2, varscan2
- SLC17A9 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs564928264, COSV64846694; called by muse, mutect2, varscan2
- SLX4 | c.3721C>T p.R1241C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as rs771835799, COSV53560333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST18 | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52483053, COSV52506573; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3435T>A p.Y1145* | Nonsense Mutation (SNP) | VAF 49/222 reads (22%) | catalogued as COSV59125517; called by muse, mutect2, varscan2
- STXBP3 | c.979C>A p.L327I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV64181433; called by muse, mutect2, varscan2
- TAOK2 | c.1507C>G p.Q503E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99664256; called by muse, varscan2
- TEX12 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1434826027, COSV54783488; called by muse, mutect2, varscan2
- TIAM2 | c.3663C>G p.D1221E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99265287; called by muse, mutect2, varscan2
- TMEM156 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs754316294, COSV60743852; called by muse, mutect2, varscan2
- TMEM183A | c.909C>G p.I303M | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs150847027, COSV100923835; called by muse, mutect2, varscan2
- TMEM26 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237707352; called by muse, mutect2
- TNFRSF1B | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs764190618, COSV100884142; called by muse, mutect2, varscan2
- TPO | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV61093251; called by muse, mutect2, varscan2
- TRIM60 | c.103T>G p.F35V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100593966; called by muse, mutect2
- TRO | c.3722G>T p.G1241V | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51496939; called by muse, mutect2, varscan2
- TWNK | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.233); catalogued as rs779199087, COSV52965831; called by muse, mutect2, varscan2
- UTRN | c.4445A>G p.Y1482C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs774394926, COSV62327790; called by mutect2, varscan2
- WDR17 | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV99707272; called by muse, mutect2
- WDR5 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV62272417; called by muse, mutect2, varscan2
- WDR7 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs141522942; called by muse, mutect2
- ZBED9 | c.3178C>T p.R1060W | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs765954782, COSV71729126; called by muse, mutect2, varscan2
- ZNF214 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99547302; called by muse, mutect2, varscan2
- AGO3 | c.543dup p.F182Ifs*9 | Frame Shift Ins (INS) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- BLVRB | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); called by muse, mutect2
- LARP4 | c.419_422delinsAAC p.L140Qfs*3 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by pindel, varscan2*
- PPP1R15A | c.344_346dup p.D115dup | In Frame Ins (INS) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- SHANK2 | c.4156_4157insG p.I1386Sfs*18 | Frame Shift Ins (INS) | VAF 19/76 reads (25%) | called by mutect2, varscan2
- SIDT1 | c.2018dup p.Q674Afs*3 | Frame Shift Ins (INS) | VAF 9/92 reads (10%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.1081C>A p.R361= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV52714778, COSV99464602; called by muse, mutect2, varscan2
- CNTN5 | c.1878C>T p.I626= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1281840556, COSV99675124; called by muse, varscan2
- COL18A1 | c.3564C>T p.G1188= (on ENST00000359759 / NM_130444.3; = p.G953= on NM_030582.4) | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs886813731, COSV60586012; called by muse, mutect2, varscan2
- EIF3M | c.243T>A p.A81= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV60072222; called by muse, varscan2
- GHITM | c.114G>A p.L38= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV64538155; called by muse, mutect2, varscan2
- GUCY2F | c.2838C>A p.G946= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99484738, COSV99485756; called by muse, varscan2
- HOXB9 | c.426G>T p.A142= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs773821975, COSV60817478; called by muse, mutect2
- HSD17B4 | c.2244C>T p.S748= (on ENST00000414835 / NM_001199291.3; = p.S723= on NM_000414.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99819669; called by muse, mutect2
- IRAG1 | c.1956G>A p.A652= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as rs540632213, COSV70209722; called by muse, mutect2, varscan2
- JCAD | c.1302T>C p.F434= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV64757665; called by muse, mutect2, varscan2
- KIRREL3 | c.1569G>A p.S523= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs768714214, COSV69383596; called by muse, mutect2, varscan2
- KLF5 | c.1317C>T p.N439= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV66613367; called by muse, mutect2, varscan2
- MEX3C | c.1626T>C p.P542= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV68529467; called by muse, mutect2
- MGAT4A | c.906G>A p.A302= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs747997417, COSV53845061; called by muse, mutect2, varscan2
- NCOA2 | c.570T>G p.P190= | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2
- OFD1 | c.2418C>T p.D806= | Silent (SNP) | VAF 68/337 reads (20%) | catalogued as COSV100406820; called by muse, mutect2, varscan2
- OPRPN | c.678C>A p.S226= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV68192522; called by muse, mutect2, varscan2
- OR1K1 | c.888C>T p.R296= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs760414236, COSV52956045; called by muse, mutect2
- OR2T6 | c.369C>T p.Y123= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs763656355, COSV63215569; called by muse, mutect2, varscan2
- OTUD7A | c.1263C>T p.D421= (on ENST00000307050 / NM_001382637.1; = p.D414= on NM_130901.3) | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- PCDH11X | c.51G>T p.V17= | Silent (SNP) | VAF 20/322 reads (6%) | catalogued as COSV53478632; called by muse, mutect2
- PCDHB3 | c.1563C>T p.Y521= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs782347010, COSV50607432, COSV50625007; called by muse, mutect2, varscan2
- PCLO | c.13687T>C p.L4563= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- PEG3 | c.3456G>A p.E1152= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV55623185; called by muse, mutect2, varscan2
- PRAMEF12 | c.564A>T p.I188= | Silent (SNP) | VAF 32/344 reads (9%) | catalogued as COSV63214627; called by muse, mutect2
- PRDM13 | c.603G>A p.A201= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV65028782; called by muse, mutect2
- PRDX1 | c.120G>T p.V40= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99423511; called by muse, mutect2
- PRPF6 | c.1227A>T p.A409= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- PSG2 | c.759A>T p.S253= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV61544491; called by muse, mutect2, varscan2
- PTPN14 | c.108G>A p.T36= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs748318666, COSV65281062; called by muse, mutect2, varscan2
- SHISA5 | c.324G>A p.A108= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs748925455, COSV99603949; called by muse, mutect2, varscan2
- SPTBN2 | c.2562C>G p.L854= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100018780; called by muse, mutect2
- SYNE1 | c.20718G>A p.Q6906= (on ENST00000367255 / NM_182961.4; = p.Q6835= on NM_033071.3) | Silent (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- TTC14 | c.1521G>A p.R507= | Silent (SNP) | VAF 17/195 reads (9%) | catalogued as COSV56009105; called by muse, mutect2
- DENND10P1 | n.301C>G | RNA (SNP) | VAF 13/210 reads (6%) | called by muse, mutect2
- LY9 | c.454+1820C>T | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as rs772038455, COSV54431226; called by muse, mutect2, varscan2
- OR3A4P | n.550G>T | RNA (SNP) | VAF 13/89 reads (15%) | catalogued as rs1200865586; called by mutect2, varscan2
- RORA | c.197-26396C>T | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99832425; called by muse, varscan2
- USH1C | c.1284+1125T>A | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as COSV50013889; called by muse, mutect2
- USH1C | c.1284+1123T>A | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as rs1565042134, COSV50013892; called by muse, mutect2
